CCDI case PBCBMM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/acca4cfe-7e0b-4ad1-b26b-04cf6bc1891b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 10.6 years (3,857 days).

Biospecimens (2 samples)
- Sample 0DNGGL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNGGS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
